Somatic mutation profile of tumor specimen HCM-STAN-0846-C20-01D (aliquot HCM-STAN-0846-C20-01D-04D-A937-36) from HCMI case HCM-STAN-0846-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 65.5 years (23,938 days).
Specimen HCM-STAN-0846-C20-01D: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8cdd8d50-3495-4017-b2de-4cd58b2bb5ed.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-STAN-0846-C20-11D (FFPE Scrolls), aliquot HCM-STAN-0846-C20-11D-04D-A937-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1956e3d-0d1d-4cfe-b85c-174e0fa644b1

The open-access MAF lists 146 somatic variants for this specimen: 112 protein-altering or splice-affecting, 30 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 30, Nonsense Mutation 9, Frame Shift Del 4, Intron 4, Frame Shift Ins 3, In Frame Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3944C>A p.S1315* | Nonsense Mutation (SNP) | VAF 87/258 reads (34%) | hotspot (GDC flag); catalogued as CM021066, CM106373, COSV57326747, COSV57328428, COSV57342242, COSV57397137; called by muse, mutect2, varscan2
- FBXW7 | c.1514G>A p.R505H (on ENST00000281708 / NM_001349798.2; = p.R425H on NM_018315.5) | Missense Mutation (SNP) | VAF 200/280 reads (71%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519896, COSV55901126, COSV55908371, COSV55911517; ClinVar: likely pathogenic / uncertain significance; called by muse, varscan2
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 185/363 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.737C>T p.P246L | Missense Mutation (SNP) | VAF 186/276 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.116); catalogued as rs587782350, CM991083, COSV64291511, COSV64305247; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 162/208 reads (78%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 38/147 reads (26%) | catalogued as COSV66865435; called by muse, mutect2, varscan2
- AMER1 | c.1489C>T p.R497* | Nonsense Mutation (SNP) | VAF 155/189 reads (82%) | catalogued as COSV57655167; called by muse, mutect2, varscan2
- ANGPTL6 | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT tolerated (0.77); PolyPhen benign (0.1); catalogued as rs757435327; called by muse, mutect2, varscan2
- ANKAR | c.1222C>T p.R408* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as rs754492412, COSV99854108; called by muse, mutect2, varscan2
- ARHGEF12 | c.1606G>A p.V536I | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1421729429; called by muse, mutect2, varscan2
- CAPN1 | c.1441C>T p.R481* | Nonsense Mutation (SNP) | VAF 68/273 reads (25%) | catalogued as rs751243573, COSV54201789; called by muse, varscan2
- CASKIN2 | c.1889A>G p.E630G | Missense Mutation (SNP) | VAF 11/324 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV58595197; called by muse, mutect2
- CCDC42 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 118/162 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs149912256; called by muse, mutect2, varscan2
- CDK8 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 99/191 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1418353379, COSV67422530; called by muse, mutect2, varscan2
- CFAP46 | c.3233C>T p.T1078M | Missense Mutation (SNP) | VAF 71/305 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as rs746752072; called by muse, mutect2, varscan2
- CNBD1 | c.1187T>G p.L396R | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2
- CPSF1 | c.1627C>T p.R543C | Missense Mutation (SNP) | VAF 127/232 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs782427901; called by muse, mutect2, varscan2
- DMD | c.4790G>C p.R1597T | Missense Mutation (SNP) | VAF 124/448 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV63744142; called by muse, mutect2, varscan2
- EPHA8 | c.488G>A p.R163H | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs757202575, COSV51262732; called by muse, mutect2, varscan2
- EXT1 | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 23/266 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.113); catalogued as rs762790189, COSV100983906; called by muse, mutect2
- EZHIP | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 48/332 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs1006910285, COSV57955307; called by muse, mutect2, varscan2
- FAM170B | c.374C>T p.T125M | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1374774215, COSV61254342; called by muse, mutect2, varscan2
- FOXD4 | c.1190G>A p.R397Q | Missense Mutation (SNP) | VAF 77/203 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1390586065; called by muse, mutect2, varscan2
- GAL3ST3 | c.949G>A p.V317M | Missense Mutation (SNP) | VAF 56/150 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.025); catalogued as COSV100360678; called by muse, mutect2, varscan2
- GALNS | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 76/186 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs377591464; called by muse, mutect2, varscan2
- HSD11B1 | c.755G>A p.R252H | Missense Mutation (SNP) | VAF 162/317 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs554862870, COSV54825694; called by muse, mutect2, varscan2
- ISM1 | c.103G>A p.A35T | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT tolerated (0.78); PolyPhen benign (0.078); catalogued as rs1160382767; called by muse, varscan2
- KCNMA1 | c.3557G>A p.R1186Q (on ENST00000286628 / NM_001161352.2; = p.R1128Q on NM_002247.4) | Missense Mutation (SNP) | VAF 82/295 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs200141207; ClinVar: uncertain significance; called by muse, varscan2
- KIRREL2 | c.332G>A p.R111H | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761189830, COSV52877346; called by muse, mutect2, varscan2
- KRTAP19-3 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 103/390 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.995); catalogued as rs1042958885, COSV61855270; called by muse, mutect2, varscan2
- LPO | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 62/422 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs140718738, COSV51858487; called by muse, mutect2, varscan2
- NUGGC | c.2087G>A p.R696Q | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as rs377099582; called by muse, mutect2, varscan2
- OR4X1 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV60722480; called by mutect2, varscan2
- PCDHGC5 | c.2237G>T p.S746I | Missense Mutation (SNP) | VAF 76/174 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.495); catalogued as COSV52757033; called by muse, mutect2, varscan2
- PCNX1 | c.6544G>A p.G2182S | Missense Mutation (SNP) | VAF 112/263 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.791); catalogued as rs775426657, COSV53091906; called by muse, mutect2, varscan2
- PON3 | c.1049T>A p.L350Q | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs948339081; called by muse, varscan2
- PSRC1 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 83/114 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as COSV64020973; called by muse, mutect2, varscan2
- RAMP1 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 176/217 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs147692476, COSV54537412; called by muse, varscan2
- RBFOX1 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs748804086, COSV100299358; called by muse, mutect2, varscan2
- SHISA9 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 55/137 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs760672521, COSV69631527; called by muse, mutect2, varscan2
- SORL1 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM166733; called by muse, mutect2, varscan2
- SYT9 | c.292C>G p.P98A | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59619988; called by muse, mutect2, varscan2
- TANC2 | c.89C>T p.P30L | Missense Mutation (SNP) | VAF 156/319 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as rs1437062053; called by muse, varscan2
- THSD1 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.811); catalogued as rs755014285, COSV51628575; called by muse, mutect2, varscan2
- TMEM117 | c.236G>A p.G79E | Missense Mutation (SNP) | VAF 85/307 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779283266; called by muse, mutect2, varscan2
- TMEM63A | c.823_825del p.E275del | In Frame Del (DEL) | VAF 42/184 reads (23%) | catalogued as rs761921126; called by mutect2, varscan2
- TTK | c.1079C>T p.T360M | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.213); catalogued as rs199645793, COSV57886377; called by muse, varscan2
- XRN1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 55/253 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.644); catalogued as COSV53816482; called by muse, mutect2, varscan2
- ABHD16B | c.74C>G p.P25R | Missense Mutation (SNP) | VAF 82/387 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- APC | c.4366_4369del p.K1456Hfs*16 | Frame Shift Del (DEL) | VAF 79/221 reads (36%) | called by mutect2, varscan2
- ASTN1 | c.457del p.H153Tfs*8 | Frame Shift Del (DEL) | VAF 54/193 reads (28%) | called by mutect2, varscan2
- BIN1 | c.1317G>T p.E439D | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BUB1B | c.3125C>T p.T1042I | Missense Mutation (SNP) | VAF 63/191 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC8 | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CCNB3 | c.341dup p.L115Afs*35 | Frame Shift Ins (INS) | VAF 35/123 reads (28%) | called by mutect2, varscan2
- CFAP54 | c.4477T>C p.F1493L | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CHD6 | c.5674C>A p.H1892N | Missense Mutation (SNP) | VAF 114/377 reads (30%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHST4 | c.554A>G p.Q185R | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CNTN6 | c.910G>T p.G304* | Nonsense Mutation (SNP) | VAF 74/366 reads (20%) | called by muse, mutect2, varscan2
- CSPG4 | c.5240T>A p.V1747E | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- CSPP1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 15/227 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.01); called by muse, mutect2
- DLGAP3 | c.605G>A p.G202E | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, varscan2
- DLGAP3 | c.604G>A p.G202R | Missense Mutation (SNP) | VAF 65/197 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- DST | c.9086A>G p.D3029G | Missense Mutation (SNP) | VAF 37/222 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2S3B | c.1030del p.D344Tfs*39 | Frame Shift Del (DEL) | VAF 120/370 reads (32%) | called by mutect2, varscan2
- EPHA5 | c.980A>G p.Y327C | Missense Mutation (SNP) | VAF 227/330 reads (69%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.706); called by muse, mutect2, varscan2
- EPHB4 | c.702C>G p.S234R | Missense Mutation (SNP) | VAF 92/374 reads (25%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESCO2 | c.1243C>A p.L415M | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- F5 | c.4895A>G p.D1632G | Missense Mutation (SNP) | VAF 78/480 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- F5 | c.25T>C p.W9R | Missense Mutation (SNP) | VAF 66/249 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, varscan2
- FAM47C | c.1396C>A p.P466T | Missense Mutation (SNP) | VAF 104/318 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FAP | c.1379A>C p.K460T | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.143); called by muse, mutect2
- FN1 | c.2798C>T p.A933V | Missense Mutation (SNP) | VAF 109/418 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FXYD2 | c.20A>G p.D7G | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, varscan2
- GFRA2 | c.464G>A p.S155N | Missense Mutation (SNP) | VAF 72/145 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPM6A | c.617A>C p.E206A | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- GPR171 | c.587dup p.L196Ffs*17 | Frame Shift Ins (INS) | VAF 54/212 reads (25%) | called by mutect2, varscan2
- HELZ2 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 13/270 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.281); called by muse, mutect2
- HSF4 | c.1064C>T p.P355L (on ENST00000521374 / NM_001040667.3; = p.P325L on NM_001538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IQGAP2 | c.2949A>T p.Q983H | Missense Mutation (SNP) | VAF 36/238 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.445); called by mutect2, varscan2
- IZUMO1 | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 57/76 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KCNMA1 | c.2624A>G p.K875R (on ENST00000286628 / NM_001161352.2; = p.K817R on NM_002247.4) | Missense Mutation (SNP) | VAF 19/378 reads (5%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2
- KCNQ3 | c.506C>G p.A169G | Missense Mutation (SNP) | VAF 176/253 reads (70%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- KDM5D | c.3722G>A p.R1241H | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- KIAA1109 | c.3167G>T p.G1056V | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- KLF6 | c.760C>A p.H254N | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL5 | c.2114T>A p.L705* | Nonsense Mutation (SNP) | VAF 12/320 reads (4%) | called by muse, mutect2
- L3MBTL3 | c.1685G>C p.G562A | Missense Mutation (SNP) | VAF 82/361 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC28 | c.805C>G p.H269D | Missense Mutation (SNP) | VAF 61/442 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRRK1 | c.434-1G>T p.X145_splice | Splice Site (SNP) | VAF 88/377 reads (23%) | called by muse, mutect2, varscan2
- MAGEL2 | c.3154C>T p.R1052* | Nonsense Mutation (SNP) | VAF 154/232 reads (66%) | called by muse, varscan2
- NCAM1 | c.1398C>A p.Y466* (on ENST00000316851 / NM_181351.5; = p.Y456* on NM_000615.7) | Nonsense Mutation (SNP) | VAF 41/132 reads (31%) | called by muse, mutect2, varscan2
- NHLH1 | c.208C>T p.R70C | Missense Mutation (SNP) | VAF 74/280 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, varscan2
- NR1D1 | c.987T>A p.H329Q | Missense Mutation (SNP) | VAF 101/444 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF17 | c.87_97del p.D29Efs*18 | Frame Shift Del (DEL) | VAF 54/159 reads (34%) | called by mutect2, varscan2
- RGSL1 | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 54/206 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- RIMS2 | c.610A>T p.S204C | Missense Mutation (SNP) | VAF 61/447 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SEMG1 | c.275A>C p.K92T | Missense Mutation (SNP) | VAF 46/248 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SLC13A1 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 79/396 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- SLC17A6 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 124/155 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- SLC44A1 | c.280_281insG p.F94Cfs*15 | Frame Shift Ins (INS) | VAF 56/190 reads (29%) | called by mutect2, varscan2
- SPATA31D1 | c.4153G>T p.V1385L | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.36); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- STRA6 | c.1164C>G p.H388Q | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- THSD7B | c.3842C>A p.T1281N (on ENST00000272643; = p.T1279N on NM_001316349.2) | Missense Mutation (SNP) | VAF 45/256 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- TPD52L1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 153/281 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIM44 | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 110/289 reads (38%) | SIFT tolerated (0.86); PolyPhen benign (0.151); called by muse, varscan2
- TRPA1 | c.2995G>T p.D999Y | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- UBR2 | c.286_288del p.S96del | In Frame Del (DEL) | VAF 56/404 reads (14%) | called by mutect2, varscan2
- USP53 | c.1033C>A p.L345I | Missense Mutation (SNP) | VAF 102/303 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XRN1 | c.147T>A p.D49E | Missense Mutation (SNP) | VAF 55/252 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF365 | c.1144C>A p.L382I | Missense Mutation (SNP) | VAF 236/422 reads (56%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); called by muse, varscan2
- ZNF729 | c.3595C>A p.Q1199K | Missense Mutation (SNP) | VAF 25/130 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ACP7 | c.234C>T p.F78= | Silent (SNP) | VAF 76/190 reads (40%) | called by muse, varscan2
- AHNAK2 | c.10518C>T p.D3506= | Silent (SNP) | VAF 140/209 reads (67%) | catalogued as rs199879973; called by muse, varscan2
- ALAS1 | c.1395G>A p.R465= | Silent (SNP) | VAF 88/265 reads (33%) | called by muse, mutect2, varscan2
- ANO1 | c.1935C>A p.S645= | Silent (SNP) | VAF 78/302 reads (26%) | called by muse, mutect2, varscan2
- CCDC168 | c.8496C>A p.I2832= | Silent (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- CCDC178 | c.2223T>C p.T741= (on ENST00000383096 / NM_001105528.3; = p.T703= on NM_198995.3) | Silent (SNP) | VAF 26/78 reads (33%) | called by muse, varscan2
- CYP2R1 | c.1465T>C p.L489= | Silent (SNP) | VAF 36/483 reads (7%) | called by muse, mutect2
- DMP1 | c.1209A>G p.Q403= | Silent (SNP) | VAF 106/239 reads (44%) | called by muse, mutect2, varscan2
- DNAH11 | c.3159C>T p.L1053= | Silent (SNP) | VAF 50/536 reads (9%) | catalogued as rs1381499126, COSV60947890, COSV60953398; called by muse, mutect2
- ELOA | c.60G>A p.E20= | Silent (SNP) | VAF 119/161 reads (74%) | called by muse, mutect2, varscan2
- ENAM | c.3264G>A p.T1088= | Silent (SNP) | VAF 129/184 reads (70%) | catalogued as rs751620386; called by muse, mutect2, varscan2
- FLG | c.11499T>G p.A3833= | Silent (SNP) | VAF 75/358 reads (21%) | called by muse, varscan2
- FOXN1 | c.492C>T p.D164= | Silent (SNP) | VAF 88/355 reads (25%) | catalogued as rs139818870; called by muse, mutect2, varscan2
- GLRB | c.216A>G p.R72= | Silent (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- GPR139 | c.801C>T p.S267= | Silent (SNP) | VAF 79/227 reads (35%) | catalogued as rs764200611; called by muse, mutect2, varscan2
- INPP5A | c.417C>T p.T139= | Silent (SNP) | VAF 104/198 reads (53%) | catalogued as rs376694651; called by muse, varscan2
- IRF2BPL | c.1326T>C p.Y442= | Silent (SNP) | VAF 119/170 reads (70%) | called by muse, mutect2, varscan2
- KIAA1109 | c.3168A>T p.G1056= | Silent (SNP) | VAF 101/311 reads (32%) | called by muse, mutect2, varscan2
- LAMA2 | c.1113G>A p.K371= | Silent (SNP) | VAF 71/273 reads (26%) | called by muse, mutect2, varscan2
- LORICRIN | c.750C>T p.S250= | Silent (SNP) | VAF 208/330 reads (63%) | catalogued as rs747527092; called by muse, varscan2
- MTCH1 | c.336G>A p.P112= | Silent (SNP) | VAF 158/252 reads (63%) | catalogued as rs755488075, COSV65320040; called by muse, varscan2
- MYH9 | c.3183C>T p.S1061= | Silent (SNP) | VAF 88/215 reads (41%) | catalogued as rs778202463, COSV99337519; called by muse, mutect2, varscan2
- NDST4 | c.1107G>T p.R369= | Silent (SNP) | VAF 75/282 reads (27%) | catalogued as COSV52119403; called by muse, mutect2, varscan2
- OR2W1 | c.762T>A p.T254= | Silent (SNP) | VAF 40/206 reads (19%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1674C>T p.N558= | Silent (SNP) | VAF 117/276 reads (42%) | catalogued as COSV65295434, COSV65296327; called by muse, mutect2, varscan2
- RAD51C | c.709C>A p.R237= | Silent (SNP) | VAF 23/137 reads (17%) | catalogued as CM148158, COSV61676239; called by muse, mutect2, varscan2
- SLC13A1 | c.396C>A p.A132= | Silent (SNP) | VAF 78/399 reads (20%) | called by muse, mutect2, varscan2
- THADA | c.3090T>G p.T1030= | Silent (SNP) | VAF 25/146 reads (17%) | called by muse, varscan2
- USP53 | c.1032A>G p.L344= | Silent (SNP) | VAF 86/271 reads (32%) | called by muse, varscan2
- VWA3A | c.1950C>T p.G650= | Silent (SNP) | VAF 83/240 reads (35%) | catalogued as rs377509870; called by muse, mutect2
- AC011503.1 | n.467+8666G>T | Intron (SNP) | VAF 34/156 reads (22%) | called by muse, mutect2, varscan2
- CXCL12 | c.266+779G>A | Intron (SNP) | VAF 91/378 reads (24%) | catalogued as rs754639751, COSV100638867; called by muse, mutect2, varscan2
- SEPTIN5 | c.55-848C>T | Intron (SNP) | VAF 8/160 reads (5%) | catalogued as rs923962436; called by muse, mutect2
- TTN | c.10361-4032A>C | Intron (SNP) | VAF 56/163 reads (34%) | called by muse, mutect2, varscan2
